Gene-level copy-number profile of tumor specimen TCGA-DD-AAVU-01A from TCGA case TCGA-DD-AAVU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 46.2 years (16,889 days).
Specimen TCGA-DD-AAVU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.affeb078-233f-4f21-9d3d-0f84afddb86b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAVU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fd1558f5-f01a-484c-9c18-82fd3f63533d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 901; copy number 2: 16,025; copy number 3: 5,458; copy number 4: 35,293; copy number 5: 493; copy number 6: 72; copy number 7: 1,536; copy number 10: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAVU-01A-11D-A40Q-01): tumor purity 0.91, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:169,702,190–170,419,325, 24 genes: C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL603783.1, AL596442.4, AL596442.3, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1, FAM120B, AL078605.1, MIR4644, AL008628.1.
- chr12:23,175,648–23,251,499, 2 genes: AC087235.2, AC087235.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,743,735–40,402,010, 15 genes, copy number 10 (within-gene range 3–10): ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1.

Autosomal genes at a single copy (total copy number 1): 901. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
